Somatic mutation profile of tumor specimen TCGA-25-2391-01A (aliquot TCGA-25-2391-01A-01W-0799-08) from TCGA case TCGA-25-2391, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.3 years (20,939 days).
Specimen TCGA-25-2391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8745d845-67fa-47df-a3af-fb200b62063b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2391-10A (Blood Derived Normal), aliquot TCGA-25-2391-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ac6f23-a977-45d2-95a6-ad09abd74f13

The open-access MAF lists 81 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 13, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV59509988; called by mutect2, varscan2
- ACTR3B | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55447573; called by muse, mutect2, varscan2
- ADCY10 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63239444; called by muse, mutect2, varscan2
- CCDC80 | c.1122A>T p.R374S | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV52815833; called by muse, mutect2, varscan2
- CHCHD6 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 14/354 reads (4%) | catalogued as COSV99336486; called by muse, mutect2
- CHD6 | c.5832G>T p.E1944D | Missense Mutation (SNP) | VAF 230/516 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100951142; called by muse, mutect2, varscan2
- DAB1 | c.1400C>A p.P467H (on ENST00000371231; = p.P434H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64691752; called by muse, mutect2, varscan2
- DOCK5 | c.4722G>T p.K1574N | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs1453188583, COSV99377122; called by muse, mutect2
- DSG4 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV57389889; called by muse, mutect2, varscan2
- EFCAB12 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550703177, COSV58175354; called by muse, mutect2, varscan2
- EVC2 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.193); catalogued as COSV100186218; called by muse, mutect2
- FBXW7 | c.2077G>A p.E693K (on ENST00000281708 / NM_001349798.2; = p.E613K on NM_018315.5) | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55901729; called by muse, mutect2, varscan2
- FLT1 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as COSV99163076; called by muse, mutect2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 272/354 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- GABBR2 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | catalogued as COSV99410444; called by muse, mutect2
- GNAT1 | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV50028930; called by muse, mutect2, varscan2
- GSK3B | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 122/771 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV51772990; called by muse, mutect2, varscan2
- HOMER1 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99981169; called by muse, mutect2
- HSF5 | c.596G>C p.S199T | Missense Mutation (SNP) | VAF 94/101 reads (93%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV60416035; called by muse, mutect2, varscan2
- IL1RN | c.288G>T p.K96N (on ENST00000409930 / NM_173842.3; = p.K78N on NM_000577.5) | Missense Mutation (SNP) | VAF 188/377 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV52080266; called by muse, mutect2, varscan2
- IL37 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.107); catalogued as COSV54490568, COSV99636450; called by muse, mutect2, varscan2
- IQCE | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.83); PolyPhen benign (0.033); catalogued as COSV58077411; called by muse, mutect2, varscan2
- KBTBD12 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV59678625; called by muse, mutect2, varscan2
- KCTD16 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV72577987; called by muse, mutect2, varscan2
- KLHL6 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 404/425 reads (95%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV100384775; called by muse, mutect2, varscan2
- KLHL6 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 399/422 reads (95%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as COSV100384778; called by muse, mutect2, varscan2
- LRRC15 | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61649816; called by muse, mutect2, varscan2
- LRRC36 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99338821; called by muse, mutect2, varscan2
- MC3R | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 191/408 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs767076441, COSV54763376; called by muse, mutect2, varscan2
- MRPL38 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53932650; called by muse, mutect2, varscan2
- MRPS18B | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs141114241; called by muse, mutect2, varscan2
- MTMR7 | c.998G>C p.S333T | Missense Mutation (SNP) | VAF 551/1538 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV99472518; called by muse, mutect2, varscan2
- MUC16 | c.27010C>G p.P9004A | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.179); catalogued as COSV67455851; called by muse, mutect2, varscan2
- NCKAP5 | c.4162C>G p.Q1388E | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV58436430, COSV58482485; called by muse, mutect2, varscan2
- NCOA3 | c.2749T>A p.S917T | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV100507710; called by muse, mutect2
- NEUROD1 | c.485G>C p.S162T | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.115); catalogued as COSV54548621, COSV54549129; called by muse, mutect2, varscan2
- NID2 | c.3506C>G p.A1169G | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV53494584; called by muse, mutect2
- NLRP4 | c.1595A>G p.H532R | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56711233; called by muse, mutect2, varscan2
- NTF3 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV58417406; called by muse, mutect2, varscan2
- OR5M11 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 209/501 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.289); catalogued as COSV73141689; called by muse, mutect2, varscan2
- PDZD2 | c.2327A>T p.D776V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56850033; called by muse, mutect2, varscan2
- PPP1R12B | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 167/399 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs139402597; called by muse, mutect2, varscan2
- PPP2R3B | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66812794; called by muse, mutect2, varscan2
- PREX2 | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 166/528 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55749465, COSV99908011; called by muse, mutect2, varscan2
- PRUNE2 | c.6019G>T p.E2007* | Nonsense Mutation (SNP) | VAF 8/113 reads (7%) | catalogued as COSV100944653; called by muse, mutect2
- RAB1B | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780097222, COSV61012253; called by muse, mutect2, varscan2
- RASA1 | c.2098G>T p.G700C | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV57193707; called by muse, mutect2, varscan2
- SEPSECS | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 32/611 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV100258860; called by muse, mutect2
- SEPTIN4 | c.82A>C p.T28P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57895325; called by muse, mutect2, varscan2
- SLC7A8 | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100328467, COSV57554184, COSV57556750; called by muse, mutect2, varscan2
- TBX15 | c.1760A>T p.Y587F (on ENST00000369429 / NM_001330677.2; = p.Y481F on NM_152380.3) | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.449); catalogued as COSV52869345; called by muse, mutect2, varscan2
- TIAM2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs373788314; called by muse, mutect2, varscan2
- TYMS | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 265/600 reads (44%) | catalogued as COSV99201089; called by muse, varscan2
- YOD1 | c.671_679del p.E224_I227delinsV | In Frame Del (DEL) | VAF 63/221 reads (29%) | catalogued as COSV60006066; called by mutect2, pindel, varscan2
- ZBED9 | c.2315A>T p.K772I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV71729139, COSV71729264; called by muse, mutect2, varscan2
- ZNF106 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 307/741 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV55515092; called by muse, mutect2, varscan2
- ZNF14 | c.1593T>A p.F531L | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV59848917; called by muse, mutect2, varscan2
- ZNF629 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.986); catalogued as COSV52697862, COSV52698572; called by muse, mutect2, varscan2
- AKAP10 | c.814dup p.T272Nfs*5 | Frame Shift Ins (INS) | VAF 169/274 reads (62%) | called by mutect2, pindel, varscan2
- ANKRD7 | c.43_49del p.S16Afs*9 | Frame Shift Del (DEL) | VAF 125/260 reads (48%) | called by mutect2, pindel, varscan2
- AP2B1 | c.2711G>C p.R904P | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PODN | c.1424G>C p.R475P (on ENST00000395871; = p.R427P on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- SRBD1 | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TP53 | c.151dup p.E51Gfs*6 | Frame Shift Ins (INS) | VAF 457/765 reads (60%) | called by mutect2, pindel, varscan2
- ZNF740 | c.274_284del p.S92Kfs*9 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ADGRA2 | c.294G>T p.G98= | Silent (SNP) | VAF 89/170 reads (52%) | catalogued as COSV59442229; called by muse, mutect2, varscan2
- AQR | c.678C>T p.I226= | Silent (SNP) | VAF 67/131 reads (51%) | catalogued as COSV50031155; called by muse, mutect2, varscan2
- ARHGEF10L | c.1893C>T p.G631= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs758570105, COSV51430112; called by muse, mutect2, varscan2
- CEPT1 | c.540T>C p.D180= | Silent (SNP) | VAF 272/620 reads (44%) | catalogued as rs567601468, COSV64110739; called by muse, mutect2, varscan2
- DSP | c.2580C>T p.V860= | Silent (SNP) | VAF 76/215 reads (35%) | catalogued as COSV65792089; called by muse, mutect2, varscan2
- FER1L5 | c.5874G>A p.S1958= (on ENST00000623019; = p.S1922= on NM_001293083.2) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs769543192, COSV53841075; called by muse, mutect2, varscan2
- GSAP | c.1944C>A p.I648= | Silent (SNP) | VAF 186/563 reads (33%) | catalogued as COSV99990276; called by muse, mutect2, varscan2
- MACF1 | c.12660A>G p.L4220= (on ENST00000372915; = p.L2153= on NM_012090.5) | Silent (SNP) | VAF 105/296 reads (35%) | catalogued as COSV57114247; called by muse, mutect2, varscan2
- NOG | c.585C>T p.S195= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV60446869; called by muse, mutect2, varscan2
- NRXN2 | c.2106G>T p.G702= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV55450383; called by muse, mutect2, varscan2
- PEX11G | c.105G>C p.L35= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV55536454; called by muse, mutect2, varscan2
- SMC2 | c.174G>A p.R58= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV53956600; called by muse, mutect2, varscan2
- SNCA | c.57T>A p.A19= | Silent (SNP) | VAF 110/137 reads (80%) | catalogued as COSV61132658; called by muse, mutect2, varscan2
- LRRC1 | c.*2G>A | 3'UTR (SNP) | VAF 32/858 reads (4%) | catalogued as rs936206474, COSV100906426; called by muse, mutect2
- SNORD115-44 | n.67G>C | RNA (SNP) | VAF 120/289 reads (42%) | called by muse, mutect2, varscan2
- TRAC | c.*42_*45del | 3'UTR (DEL) | VAF 56/176 reads (32%) | called by pindel, varscan2
